MMRF case MMRF_1289 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b4f423b6-71b9-459a-a5ed-93208ec27397

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.8 years (19,663 days); ISS stage: III; Days to last known disease status: 487 days (1.3 years); Days to last follow up: 487 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 49 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 219 days; Days to treatment end: 295 days.
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 330 days; Days to treatment end: 393 days (1.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 393 days (1.1 years); Days to treatment end: 417 days (1.1 years).
   Treatment given: Therapeutic agents: Carmustine + Cyclophosphamide + Melphalan + Prednisone + Vincristine; Regimen or line of therapy: Third line of therapy; Days to treatment start: 465 days (1.3 years); Days to treatment end: 477 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 487.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6: M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 4.08 g/L; Immunoglobulin A 47.3 g/L; Immunoglobulin M 0.214 g/L; Beta 2 Microglobulin 6.6 µg/mL; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 10.7 g/dL; Glucose 5.28 mmol/L.
- Day 88: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 5.37 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 1.3 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.9 ×10⁹/L; Platelets 55 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 6.55 mmol/L.
- Day 190 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 6.2 g/L; Immunoglobulin A 0.389 g/L; Immunoglobulin M 0.295 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 5.28 mmol/L.
- Day 275 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.67 ×10⁹/L; Platelets 354 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 393: M Protein 0.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 4.4 g/L; Immunoglobulin A 8.92 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 6.77 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.95 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 7.92 mmol/L.
- Day 456 (ECOG 2): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.03 mg/dL; Immunoglobulin G 3.73 g/L; Immunoglobulin A 5.3 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 478 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day -6: Weight: 73 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: male.

Biospecimens (1 sample)
- Sample MMRF_1289_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
